Somatic mutation profile of tumor specimen TARGET-20-PASBCT-09A (aliquot TARGET-20-PASBCT-09A-01D) from TARGET case TARGET-20-PASBCT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,942 days).
Specimen TARGET-20-PASBCT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e412836-baa6-4849-9b0d-1634e3f7ab46.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBCT-14A (Bone Marrow Normal), aliquot TARGET-20-PASBCT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5f283b4-d1b0-4e69-9246-f7d5018685ac

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, In Frame Ins 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K3 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779727093; called by muse, mutect2
- PCDH9 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRCAP | c.977_978insA p.E327* | Frame Shift Ins (INS) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- WT1 | c.1341_1355dup p.S451_D452insEFSRS | In Frame Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- EP400 | c.8931G>A p.A2977= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs373215107; called by muse, mutect2, varscan2
